Somatic mutation profile of tumor specimen TCGA-S9-A6U5-01A (aliquot TCGA-S9-A6U5-01A-12D-A33T-08) from TCGA case TCGA-S9-A6U5, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.0 years (12,417 days).
Specimen TCGA-S9-A6U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 061a24b9-bb30-4842-a1a8-9c9f24452e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U5-10A (Blood Derived Normal), aliquot TCGA-S9-A6U5-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d401d49-cc30-4ba4-a349-99bad903221c

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 7/31 reads (23%) | hotspot (GDC flag); called by mutect2, pindel
- ASPM | c.9360T>A p.N3120K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99660441; called by muse, mutect2
- FRRS1 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99789936; called by muse, mutect2, varscan2
- GNB3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs1429928202, COSV99301266; called by muse, mutect2
- ITGB6 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200145370, COSV51792943; called by muse, mutect2, varscan2
- MARCKSL1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 87/123 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs757947035, COSV100269592; called by muse, mutect2, varscan2
- NHLRC2 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs370450558; called by muse, mutect2, varscan2
- OPCML | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV100101729; called by muse, mutect2, varscan2
- PDGFC | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99925421; called by muse, mutect2, varscan2
- PFKL | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1436725175, COSV62463705, COSV62465065; called by muse, mutect2, varscan2
- PHOX2B | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99891276; called by muse, mutect2, varscan2
- SPP1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV99421064; called by muse, mutect2, varscan2
- CIC | c.4431_4432del p.F1478Sfs*35 | Frame Shift Del (DEL) | VAF 64/141 reads (45%) | called by pindel, varscan2
- KIAA0930 | c.261dup p.K88Qfs*10 (on ENST00000336156 / NM_001009880.2; = p.K93Qfs*10 on NM_015264.2) | Frame Shift Ins (INS) | VAF 51/123 reads (41%) | called by mutect2, pindel, varscan2
- SLC7A7 | c.1499_1503del p.G500Dfs*10 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- ADCY10 | c.1119C>T p.C373= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as rs1477599594, COSV100896888; called by muse, mutect2
- COL4A1 | c.138A>G p.G46= | Silent (SNP) | VAF 217/555 reads (39%) | catalogued as COSV101011199; called by muse, mutect2, varscan2
- GSTM2 | c.27C>T p.N9= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99598243; called by muse, mutect2, varscan2
- IGKV1-12 | c.240C>A p.V80= | Silent (SNP) | VAF 46/173 reads (27%) | called by mutect2, varscan2
- MYO1C | c.1950G>A p.G650= (on ENST00000648651 / NM_001080779.2; = p.G615= on NM_033375.5) | Silent (SNP) | VAF 17/254 reads (7%) | catalogued as COSV100704378; called by muse, mutect2
- PLCL1 | c.2229G>A p.G743= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs142477843; called by muse, mutect2
- SCRT1 | c.909C>T p.H303= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100146470; called by muse, mutect2, varscan2
- TBX4 | c.1050C>T p.C350= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV53608224; called by muse, mutect2, varscan2
